Somatic mutation profile of tumor specimen TCGA-YC-A8S6-01A (aliquot TCGA-YC-A8S6-01A-31D-A38G-08) from TCGA case TCGA-YC-A8S6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 71.5 years (26,130 days).
Specimen TCGA-YC-A8S6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd0efbeb-faca-44ce-bff1-050424b85750.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YC-A8S6-10A (Blood Derived Normal), aliquot TCGA-YC-A8S6-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd58d8eb-1b07-450b-9d3a-2f9a1511e0fd

The open-access MAF lists 103 somatic variants for this specimen: 82 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 19, Nonsense Mutation 8, Splice Site 4, Frame Shift Del 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.1063A>C p.T355P | Missense Mutation (SNP) | VAF 13/137 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57251216, COSV57256291; called by muse, mutect2
- HRAS | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 11/175 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2
- PACS2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs1555408401, COSV100330680; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.4276C>G p.L1426V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99558961; called by muse, mutect2
- ACCSL | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs755691880, COSV66581556; called by muse, mutect2, varscan2
- ADGRL2 | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54673052; called by muse, mutect2, varscan2
- ADGRL3 | c.1454C>T p.S485F (on ENST00000506720 / NM_001322402.2; = p.S417F on NM_015236.6) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV101546984, COSV101547194; called by muse, mutect2
- ADNP2 | c.2346C>G p.I782M | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.509); catalogued as COSV51539844, COSV51541006; called by muse, mutect2, varscan2
- APAF1 | c.1078G>A p.D360N (on ENST00000551964 / NM_181861.2; = p.D349N on NM_001160.3) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV59665214; called by muse, mutect2, varscan2
- ASNSD1 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99641098; called by muse, mutect2, varscan2
- C9orf78 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV59615285, COSV59616762; called by muse, mutect2, varscan2
- C9orf78 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as COSV59621704; called by muse, mutect2
- CAPRIN1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100403728, COSV100403787, COSV58219592; called by muse, mutect2, varscan2
- CEMIP | c.1340C>G p.S447C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54994866; called by muse, mutect2, varscan2
- CHRNB2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV100872582; called by muse, mutect2
- CRAT | c.410+2T>C p.X137_splice | Splice Site (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100539924; called by muse, mutect2
- CRISP1 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV59994129, COSV59995006; called by muse, mutect2
- DCAF12 | c.298C>G p.H100D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV63512907; called by muse, mutect2, varscan2
- DNAJC8 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as COSV55281889, COSV99746092; called by muse, mutect2
- EEF1AKMT1 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66964780; called by muse, mutect2, varscan2
- EXTL3 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.099); catalogued as COSV55038138; called by muse, mutect2
- FAM120A | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 23/146 reads (16%) | catalogued as COSV52912930; called by muse, mutect2, varscan2
- FAM120A | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.324); catalogued as COSV99465060, COSV99465142; called by muse, mutect2
- FLNC | c.4182G>C p.K1394N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57957933; called by muse, mutect2, varscan2
- FLRT3 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54002143; called by muse, mutect2, varscan2
- FMO1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs751584026, COSV61445439, COSV61446295; called by muse, mutect2, varscan2
- FOCAD | c.2962-1G>A p.X988_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as COSV58101573; called by muse, mutect2, varscan2
- FRYL | c.8290G>A p.E2764K | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.777); catalogued as COSV51950724; called by muse, mutect2, varscan2
- GAB2 | c.1481C>A p.T494K (on ENST00000361507 / NM_080491.3; = p.T456K on NM_012296.3) | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV60868754; called by muse, mutect2, varscan2
- GCSH | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 20/169 reads (12%) | catalogued as COSV100202814, COSV59602024; called by muse, mutect2, varscan2
- H3C11 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV58900424; called by muse, mutect2
- ING1 | c.1021del p.A341Rfs*26 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as COSV58167301; called by mutect2, pindel, varscan2
- INSRR | c.2849G>A p.R950K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV63874679; called by muse, mutect2, varscan2
- IRAK4 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71210570; called by muse, mutect2, varscan2
- IRS4 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV64533169, COSV64534373; called by muse, mutect2, varscan2
- KAT2B | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99769115; called by muse, mutect2
- KCNK9 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as rs201337202, COSV57282477; called by muse, mutect2, varscan2
- KMT2C | c.9694G>T p.E3232* | Nonsense Mutation (SNP) | VAF 13/145 reads (9%) | catalogued as COSV100070226; called by muse, mutect2
- KMT2C | c.1470-2A>G p.X490_splice | Splice Site (SNP) | VAF 13/116 reads (11%) | catalogued as COSV51454407; called by muse, mutect2, varscan2
- LCOR | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV63631319; called by muse, mutect2, varscan2
- LCOR | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); catalogued as COSV63631330; called by muse, mutect2, varscan2
- LEO1 | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.154); catalogued as COSV55176202; called by muse, mutect2, varscan2
- LEO1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs746778978, COSV55176209; called by muse, mutect2
- MAP3K6 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58872678; called by muse, mutect2, varscan2
- MAS1L | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV101009669; called by muse, mutect2
- MDN1 | c.5950G>A p.E1984K | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs758445963, COSV65523534; called by muse, mutect2, varscan2
- MEF2C | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60933478; called by muse, mutect2, varscan2
- MYT1L | c.3038C>T p.S1013L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV67703155; called by muse, mutect2, varscan2
- NDUFA9 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.51); catalogued as COSV56929838; called by muse, mutect2, varscan2
- NOP53 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV54409249, COSV99622309; called by muse, varscan2
- NOP53 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54409254, COSV99622239; called by muse, varscan2
- NUP155 | c.2261G>A p.G754E (on ENST00000231498 / NM_153485.3; = p.G695E on NM_004298.4) | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV51531138; called by muse, mutect2
- OR14J1 | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV65845506, COSV65845750; called by muse, mutect2, varscan2
- OR5AR1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV57254255, COSV57255618; called by muse, mutect2, varscan2
- PAK2 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100506103, COSV59082119; called by muse, mutect2
- PEX7 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59250088; called by muse, mutect2, varscan2
- PHYHIPL | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV65848931; called by muse, mutect2, varscan2
- PPP1R13B | c.2791G>A p.A931T | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs536152556, COSV52452983; called by muse, mutect2, varscan2
- RAI1 | c.4259C>G p.S1420C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as COSV55394452; called by muse, mutect2, varscan2
- RAI1 | c.4889C>G p.S1630C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV55394464; called by muse, mutect2, varscan2
- RBM8A | c.128-1G>C p.X43_splice | Splice Site (SNP) | VAF 7/78 reads (9%) | catalogued as rs1559231852, COSV57162796; called by muse, mutect2
- RFC1 | c.3360C>G p.I1120M (on ENST00000381897 / NM_001363496.2; = p.I1119M on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56466477; called by muse, mutect2
- RIPK4 | c.2227G>A p.D743N (on ENST00000352483; = p.D695N on NM_020639.3) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs377386951; called by muse, mutect2, varscan2
- RIPK4 | c.1413G>T p.M471I (on ENST00000352483; = p.M423I on NM_020639.3) | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs1176677535, COSV60187972; called by muse, mutect2, varscan2
- RUSC2 | c.2604G>C p.E868D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.16); catalogued as rs371634731, COSV63429091; called by muse, mutect2, varscan2
- SDK1 | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV67374478; called by muse, varscan2
- SLC10A2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs201821506; ClinVar: uncertain significance; called by muse, mutect2
- SLC43A2 | c.1362C>A p.F454L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56769675; called by muse, mutect2, varscan2
- SLX4 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs766080551, COSV53565184; called by muse, mutect2, varscan2
- SOHLH2 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV65901380, COSV65902518; called by muse, mutect2
- SRCAP | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV52675006; called by muse, mutect2
- SSX7 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1556767107, COSV53340269, COSV99994083; called by muse, mutect2
- STAG2 | c.2740C>T p.Q914* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as rs1216415127, COSV54350608, COSV54351549; called by muse, mutect2, varscan2
- STON1 | c.32C>A p.T11N | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59132333; called by muse, mutect2
- TGM5 | c.1474C>T p.R492W (on ENST00000220420 / NM_201631.4; = p.R410W on NM_004245.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763381962, COSV55009870, COSV55012003; called by muse, mutect2, varscan2
- TTF1 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57505058; called by muse, mutect2, varscan2
- TYK2 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs1407480759, COSV99314543; called by muse, mutect2, varscan2
- ZNF391 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV55123187; called by muse, mutect2, varscan2
- ARID1A | c.4806del p.S1602Rfs*10 | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | called by mutect2, pindel*, varscan2
- IGLV1-40 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCDHB9 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- TAF15 | c.759C>G p.F253L (on ENST00000605844 / NM_139215.3; = p.F250L on NM_003487.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- AP3S2 | c.117C>T p.V39= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV60518778; called by muse, mutect2
- ATF1 | c.540G>A p.Q180= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV50394878, COSV50394903; called by muse, mutect2, varscan2
- BDKRB2 | c.345C>T p.I115= | Silent (SNP) | VAF 35/184 reads (19%) | catalogued as rs1453672571, COSV60015379; called by muse, mutect2, varscan2
- CPED1 | c.2556C>T p.G852= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV60005087; called by muse, mutect2
- CUX2 | c.3744G>A p.P1248= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs372290639, COSV55629822; called by muse, mutect2, varscan2
- EHD2 | c.1401G>T p.L467= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV54409243; called by muse, mutect2, varscan2
- FAM90A1 | c.753C>T p.L251= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs761515826, COSV56709690, COSV56712843; called by muse, mutect2
- FTCD | c.1449G>T p.A483= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- IL20 | c.33C>G p.L11= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV65584699; called by muse, mutect2, varscan2
- KCNK6 | c.528G>A p.L176= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs1470925372, COSV54579860; called by muse, varscan2
- MAP3K6 | c.2559G>A p.G853= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV58872669; called by muse, mutect2, varscan2
- MDN1 | c.5193C>A p.T1731= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV101021071; called by muse, mutect2
- MROH5 | c.2988G>A p.Q996= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV71301955; called by muse, mutect2, varscan2
- NAP1L2 | c.318G>A p.V106= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV65172643; called by muse, mutect2, varscan2
- NR1H3 | c.337C>T p.L113= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV68008511; called by muse, mutect2, varscan2
- PCDHA13 | c.1122G>T p.V374= | Silent (SNP) | VAF 6/139 reads (4%) | catalogued as rs373348994, COSV56514919; called by muse, mutect2
- SGMS1 | c.738G>A p.P246= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs759281143, COSV62370996; called by muse, mutect2, varscan2
- TULP1 | c.1506C>T p.I502= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57692954; called by muse, varscan2
- VILL | c.510G>A p.K170= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV52183308, COSV52185436; called by muse, mutect2, varscan2
- C3P1 | n.3248G>C | RNA (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- CCDC30 | c.385-6168G>C | Intron (SNP) | VAF 5/73 reads (7%) | catalogued as COSV59607331; called by muse, mutect2
